Somatic mutation profile of tumor specimen MMRF_1795_1_BM_CD138pos (aliquot MMRF_1795_1_BM_CD138pos_T1_KBS5U_K11333) from MMRF case MMRF_1795, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 75.8 years (27,668 days).
Specimen MMRF_1795_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5c5898f-2965-41c0-ba5c-079e5dadee1f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1795_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1795_1_PB_Whole_C2_KBS5U_K11334; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff5eb7e8-bd31-4798-b9b0-44817906a419

The open-access MAF lists 143 somatic variants for this specimen: 56 protein-altering or splice-affecting, 13 silent, 74 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 52, Missense Mutation 47, Silent 13, 5'UTR 10, Intron 7, 3'Flank 4, Frame Shift Del 3, Splice Region 2, Frame Shift Ins 2, 5'Flank 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GCDH | c.641C>T p.T214M | Missense Mutation (SNP) | VAF 60/244 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1131692030; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- APAF1 | c.1249G>T p.E417* (on ENST00000551964 / NM_181861.2; = p.E406* on NM_001160.3) | Nonsense Mutation (SNP) | VAF 24/44 reads (55%) | catalogued as COSV59668381; called by muse, mutect2, varscan2
- CREB3L3 | c.739del p.I247Sfs*57 | Frame Shift Del (DEL) | VAF 25/102 reads (25%) | catalogued as CX115357; called by mutect2, pindel, varscan2
- DCX | c.980C>A p.P327H (on ENST00000636035 / NM_001195553.2; = p.P322H on NM_000555.3) | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as rs1453286620, COSV100576775; called by muse, mutect2, varscan2
- DGKE | c.1139C>G p.A380G | Missense Mutation (SNP) | VAF 67/150 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52349276; called by muse, mutect2, varscan2
- F8 | c.5873G>A p.R1958K | Missense Mutation (SNP) | VAF 5/143 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV64274959; called by muse, mutect2
- GPR156 | c.1612C>T p.R538W | Missense Mutation (SNP) | VAF 88/276 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.183); catalogued as rs150101992; called by mutect2, varscan2
- GPRASP2 | c.1661C>T p.T554I | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as rs1380580793; called by muse, mutect2, varscan2
- HOXD1 | c.589G>A p.G197S | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs919230567; called by muse, mutect2, varscan2
- KSR2 | c.1811G>A p.G604E | Missense Mutation (SNP) | VAF 67/141 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs765242951, COSV56666019; called by muse, mutect2, varscan2
- MATN2 | c.1673G>A p.R558H | Missense Mutation (SNP) | VAF 72/156 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs374039867; called by muse, mutect2, varscan2
- NFE2L3 | c.205G>A p.G69R | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs1212940617; called by muse, mutect2, varscan2
- OR2B11 | c.731C>T p.T244M | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141064927, COSV100275824; called by muse, mutect2, varscan2
- OR2Y1 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 140/521 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as rs780380357; called by muse, mutect2, varscan2
- PCYOX1L | c.165C>G p.I55M | Missense Mutation (SNP) | VAF 53/220 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99199211; called by muse, mutect2, varscan2
- SLC35E4 | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.65); PolyPhen benign (0.005); catalogued as rs755179385, COSV100299150; called by muse, mutect2, varscan2
- STRN | c.824G>T p.S275I | Missense Mutation (SNP) | VAF 60/217 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as COSV55747631; called by muse, mutect2, varscan2
- WDR75 | c.1890G>T p.Q630H | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs755108092; called by muse, mutect2, varscan2
- ZFP36L2 | c.1070C>T p.S357L | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs750888768, COSV99143998; called by muse, mutect2, varscan2
- ABCB8 | c.611T>C p.V204A (on ENST00000297504 / NM_001282291.2; = p.V187A on NM_007188.5) | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ASXL1 | c.637G>A p.G213S | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.49); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- CLECL1 | c.484dup p.M162Nfs*5 | Frame Shift Ins (INS) | VAF 72/197 reads (37%) | called by mutect2, pindel, varscan2
- COL12A1 | c.5926C>G p.P1976A | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- CPAMD8 | c.4414G>C p.A1472P (on ENST00000651564; = p.A1425P on NM_015692.5) | Missense Mutation (SNP) | VAF 46/164 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- CTSB | c.802del p.Q268Nfs*7 | Frame Shift Del (DEL) | VAF 17/49 reads (35%) | called by mutect2, pindel, varscan2
- DCAF1 | c.1403T>A p.F468Y | Missense Mutation (SNP) | VAF 52/201 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- EVPL | c.4318C>T p.R1440W | Missense Mutation (SNP) | VAF 76/154 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EYS | c.9076G>A p.E3026K (on ENST00000370621 / NM_001292009.1; = p.E3005K on NM_001142800.2) | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- GAS7 | c.1014G>T p.K338N (on ENST00000432992 / NM_201433.2; = p.K198N on NM_003644.3) | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- GNA12 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 107/165 reads (65%) | SIFT tolerated (0.3); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- GNA15 | c.964G>A p.G322R | Missense Mutation (SNP) | VAF 49/210 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- GNS | c.995G>A p.G332E | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRIA1 | c.1089C>A p.N363K | Missense Mutation (SNP) | VAF 61/250 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- IGHD2-8 | c.4A>G p.I2V | Missense Mutation (SNP) | VAF 30/30 reads (100%) | called by muse, varscan2
- IGLV4-3 | c.220A>G p.S74G | Missense Mutation (SNP) | VAF 51/102 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- KMT2E | c.3954C>G p.F1318L | Missense Mutation (SNP) | VAF 74/256 reads (29%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LPCAT1 | c.1257C>A p.D419E | Missense Mutation (SNP) | VAF 90/281 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LTV1 | c.82C>A p.P28T | Missense Mutation (SNP) | VAF 87/219 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYH4 | c.4061A>G p.E1354G | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- NEU4 | c.463G>T p.A155S (on ENST00000391969 / NM_001167602.3; = p.A167S on NM_080741.4) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- NPM1 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- NUP210L | c.985A>T p.T329S | Missense Mutation (SNP) | VAF 69/206 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OBSL1 | c.4609+8C>T | Splice Region (SNP) | VAF 36/100 reads (36%) | called by muse, mutect2, varscan2
- PCLO | c.2352G>T p.Q784H | Missense Mutation (SNP) | VAF 81/250 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- PPCDC | c.15del p.S6Pfs*8 | Frame Shift Del (DEL) | VAF 128/326 reads (39%) | called by mutect2, pindel, varscan2
- RAB35 | c.229dup p.Y77Lfs*35 | Frame Shift Ins (INS) | VAF 45/112 reads (40%) | called by mutect2, pindel, varscan2
- RESF1 | c.1319A>C p.N440T | Missense Mutation (SNP) | VAF 68/148 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- RP1 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RPN2 | c.1512G>T p.K504N | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- RRN3 | c.532+1G>A p.X178_splice | Splice Site (SNP) | VAF 9/31 reads (29%) | called by muse, mutect2, varscan2
- SDK1 | c.2604G>A p.V868= | Splice Region (SNP) | VAF 22/89 reads (25%) | called by muse, mutect2, varscan2
- SNCAIP | c.1804T>A p.S602T | Missense Mutation (SNP) | VAF 10/149 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.054); called by muse, mutect2
- THAP5 | c.898G>A p.D300N (on ENST00000415914 / NM_001130475.3; = p.D258N on NM_182529.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 104/308 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- TMEM192 | c.608A>T p.E203V | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ZNF33B | c.391A>C p.S131R | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.4); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF845 | c.941T>A p.L314H | Missense Mutation (SNP) | VAF 94/298 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- A2M | c.3321C>T p.I1107= | Silent (SNP) | VAF 26/53 reads (49%) | catalogued as rs1204428116, COSV59384908; called by muse, mutect2, varscan2
- CD83 | c.438C>T p.V146= | Silent (SNP) | VAF 86/261 reads (33%) | called by muse, mutect2, varscan2
- CRIP2 | c.153G>T p.P51= | Silent (SNP) | VAF 6/83 reads (7%) | called by muse, mutect2
- KBTBD13 | c.393C>T p.D131= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as rs544721592, COSV71351779; called by muse, mutect2, varscan2
- MATN4 | c.1116A>T p.A372= (on ENST00000372754; = p.A331= on NM_003833.4) | Silent (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- MYH14 | c.1014C>T p.P338= | Silent (SNP) | VAF 59/205 reads (29%) | catalogued as rs555327826; called by muse, mutect2, varscan2
- OTOF | c.660G>C p.S220= | Silent (SNP) | VAF 21/79 reads (27%) | called by muse, mutect2, varscan2
- PSD2 | c.1629C>T p.Y543= | Silent (SNP) | VAF 122/164 reads (74%) | catalogued as rs751218360, COSV51197070; called by muse, mutect2, varscan2
- SIRT2 | c.180C>T p.D60= | Silent (SNP) | VAF 97/148 reads (66%) | catalogued as rs201677615; called by muse, mutect2, varscan2
- SNAP91 | c.2712G>A p.K904= | Silent (SNP) | VAF 93/207 reads (45%) | called by muse, mutect2, varscan2
- TENM2 | c.7341C>T p.N2447= (on ENST00000518659 / NM_001122679.2; = p.N2208= on NM_001080428.3) | Silent (SNP) | VAF 33/132 reads (25%) | catalogued as rs1255686621; called by muse, mutect2, varscan2
- VIRMA | c.4833T>C p.P1611= | Silent (SNP) | VAF 49/103 reads (48%) | called by muse, mutect2, varscan2
- ZNF600 | c.927A>G p.K309= | Silent (SNP) | VAF 46/155 reads (30%) | called by muse, mutect2, varscan2
- ADAM23 | c.*1018A>G | 3'UTR (SNP) | VAF 22/92 reads (24%) | catalogued as rs1365190547; called by muse, mutect2, varscan2
- ADSS2 | c.*528A>G | 3'UTR (SNP) | VAF 20/69 reads (29%) | catalogued as rs761772668; called by muse, mutect2, varscan2
- AIMP1 | c.*222G>A | 3'UTR (SNP) | VAF 41/89 reads (46%) | called by muse, mutect2, varscan2
- BTG2 | c.-1C>T | 5'UTR (SNP) | VAF 43/159 reads (27%) | called by muse, mutect2, varscan2
- C21orf58 | c.-391G>A | 5'UTR (SNP) | VAF 85/334 reads (25%) | called by muse, varscan2
- C3orf14 | chr3:62333847 C>T | 3'Flank (SNP) | VAF 30/121 reads (25%) | catalogued as rs893338848; called by muse, mutect2, varscan2
- CDC14B | c.*187T>A | 3'UTR (SNP) | VAF 64/202 reads (32%) | called by muse, mutect2, varscan2
- CEP350 | c.*836C>T | 3'UTR (SNP) | VAF 24/93 reads (26%) | called by muse, mutect2, varscan2
- CLIP2 | c.*1300A>G | 3'UTR (SNP) | VAF 22/107 reads (21%) | called by muse, mutect2, varscan2
- CPEB4 | c.*3831C>G | 3'UTR (SNP) | VAF 31/131 reads (24%) | called by muse, mutect2, varscan2
- CUX1 | c.*6203G>A | 3'UTR (SNP) | VAF 38/116 reads (33%) | catalogued as rs145697418; called by muse, mutect2, varscan2
- DENND3 | c.384-1214T>C | Intron (SNP) | VAF 9/22 reads (41%) | called by muse, mutect2, varscan2
- DKK2 | c.-144G>A | 5'UTR (SNP) | VAF 56/125 reads (45%) | called by muse, mutect2, varscan2
- DPP6 | c.*999A>C | 3'UTR (SNP) | VAF 28/53 reads (53%) | catalogued as rs1204484692; called by muse, mutect2, varscan2
- EHHADH | c.*1516_*1518del | 3'UTR (DEL) | VAF 24/84 reads (29%) | catalogued as rs928680613; called by pindel, varscan2
- EIF5A2 | c.*1313T>G | 3'UTR (SNP) | VAF 29/53 reads (55%) | called by muse, mutect2, varscan2
- EML3 | c.1656+29G>A | Intron (SNP) | VAF 83/230 reads (36%) | called by muse, mutect2, varscan2
- EOLA1 | c.*192G>A | 3'UTR (SNP) | VAF 70/210 reads (33%) | called by muse, mutect2
- EPM2A | chr6:145735646 G>A | 5'Flank (SNP) | VAF 29/45 reads (64%) | called by muse, mutect2, varscan2
- ERC2 | c.1075-54T>C | Intron (SNP) | VAF 16/57 reads (28%) | called by muse, mutect2, varscan2
- EVI2A | c.*663A>C | 3'UTR (SNP) | VAF 46/110 reads (42%) | called by muse, mutect2, varscan2
- EVI2A | c.*558A>T | 3'UTR (SNP) | VAF 22/52 reads (42%) | called by muse, varscan2
- EVI2A | c.*497G>C | 3'UTR (SNP) | VAF 22/43 reads (51%) | called by muse, varscan2
- GOLGA5 | c.*86C>T | 3'UTR (SNP) | VAF 76/145 reads (52%) | called by muse, mutect2, varscan2
- H1-0 | c.-108C>T | 5'UTR (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
- HDAC4 | c.*3360G>A | 3'UTR (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- INPP4B | chr4:142025807 T>C | 3'Flank (SNP) | VAF 29/65 reads (45%) | called by muse, mutect2, varscan2
- ITGB6 | c.*1947A>T | 3'UTR (SNP) | VAF 29/93 reads (31%) | called by muse, mutect2, varscan2
- ITGB8 | c.*745dup | 3'UTR (INS) | VAF 33/99 reads (33%) | called by mutect2, pindel, varscan2
- KIF1C | c.*2656G>A | 3'UTR (SNP) | VAF 60/111 reads (54%) | called by muse, mutect2, varscan2
- LONRF2 | c.*5737G>A | 3'UTR (SNP) | VAF 56/150 reads (37%) | catalogued as rs753295903; called by mutect2, varscan2
- LONRF2 | c.*1479T>C | 3'UTR (SNP) | VAF 6/34 reads (18%) | called by muse, varscan2
- LONRF2 | c.*1416T>C | 3'UTR (SNP) | VAF 15/55 reads (27%) | called by muse, mutect2, varscan2
- LRRD1 | chr7:92142693 C>T | 3'Flank (SNP) | VAF 13/44 reads (30%) | catalogued as rs1297934369; called by muse, mutect2, varscan2
- MIEF1 | c.*3681T>C | 3'UTR (SNP) | VAF 17/36 reads (47%) | called by muse, mutect2, varscan2
- MIR3916 | chr1:247201854 T>C | 3'Flank (SNP) | VAF 18/30 reads (60%) | called by muse, mutect2, varscan2
- MPPED2 | c.*335A>C | 3'UTR (SNP) | VAF 39/127 reads (31%) | called by muse, mutect2, varscan2
- MYO1E | c.-92C>G | 5'UTR (SNP) | VAF 87/111 reads (78%) | catalogued as rs528359750; called by muse, varscan2
- NNT | c.*56G>A | 3'UTR (SNP) | VAF 14/364 reads (4%) | called by muse, mutect2
- NUP160 | c.3450+322G>A | Intron (SNP) | VAF 33/124 reads (27%) | called by muse, mutect2, varscan2
- NUP42 | c.-7C>T | 5'UTR (SNP) | VAF 48/248 reads (19%) | catalogued as rs780883616; called by muse, mutect2, varscan2
- OFD1 | c.-162C>T | 5'UTR (SNP) | VAF 38/76 reads (50%) | called by muse, mutect2, varscan2
- PADI1 | c.*1519G>A | 3'UTR (SNP) | VAF 53/107 reads (50%) | called by muse, mutect2, varscan2
- PAPOLG | c.*2121T>G | 3'UTR (SNP) | VAF 92/138 reads (67%) | called by muse, mutect2, varscan2
- PAPPA | c.*1984C>A | 3'UTR (SNP) | VAF 172/352 reads (49%) | called by muse, mutect2, varscan2
- PAPSS2 | c.-344C>T | 5'UTR (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- PCDH11X | c.*4186G>A | 3'UTR (SNP) | VAF 133/276 reads (48%) | called by muse, mutect2, varscan2
- PLCXD3 | c.*1635G>A | 3'UTR (SNP) | VAF 61/103 reads (59%) | catalogued as rs931606451; called by muse, mutect2, varscan2
- PLEKHA3 | c.*880A>T | 3'UTR (SNP) | VAF 21/88 reads (24%) | called by muse, mutect2, varscan2
- PLK3 | c.*153C>G | 3'UTR (SNP) | VAF 36/91 reads (40%) | catalogued as COSV100221150; called by muse, mutect2, varscan2
- POLR2C | c.*432C>T | 3'UTR (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- POLR3F | c.*278C>A | 3'UTR (SNP) | VAF 8/72 reads (11%) | called by muse, mutect2
- PRKAA2 | c.*3172T>C | 3'UTR (SNP) | VAF 26/61 reads (43%) | called by muse, mutect2, varscan2
- PSD3 | c.*4257G>A | 3'UTR (SNP) | VAF 18/29 reads (62%) | called by muse, mutect2, varscan2
- RAI14 | c.*969A>T | 3'UTR (SNP) | VAF 32/87 reads (37%) | called by muse, mutect2, varscan2
- RASEF | c.*2312C>A | 3'UTR (SNP) | VAF 36/131 reads (27%) | called by muse, mutect2, varscan2
- RHO | c.*579A>G | 3'UTR (SNP) | VAF 28/101 reads (28%) | catalogued as rs889686368; called by muse, mutect2, varscan2
- SEMA5A | c.*1196G>C | 3'UTR (SNP) | VAF 42/64 reads (66%) | called by muse, mutect2, varscan2
- SLC1A4 | c.*613G>T | 3'UTR (SNP) | VAF 40/125 reads (32%) | called by muse, mutect2, varscan2
- SMIM8 | c.*262T>C | 3'UTR (SNP) | VAF 37/70 reads (53%) | called by muse, mutect2, varscan2
- SNTB1 | c.*1531T>G | 3'UTR (SNP) | VAF 77/151 reads (51%) | called by muse, mutect2, varscan2
- SOX11 | c.*4274G>A | 3'UTR (SNP) | VAF 22/63 reads (35%) | called by muse, mutect2, varscan2
- SSTR4 | c.*42G>T | 3'UTR (SNP) | VAF 56/147 reads (38%) | catalogued as rs757154553; called by muse, mutect2, varscan2
- SUB1 | c.*880T>G | 3'UTR (SNP) | VAF 60/179 reads (34%) | called by muse, mutect2, varscan2
- SYTL4 | c.1006-404C>A | Intron (SNP) | VAF 15/32 reads (47%) | called by muse, mutect2, varscan2
- TCAIM | c.*1569C>T | 3'UTR (SNP) | VAF 39/111 reads (35%) | called by muse, mutect2, varscan2
- TM2D2 | c.*464T>C | 3'UTR (SNP) | VAF 37/69 reads (54%) | called by muse, mutect2, varscan2
- TMEM131L | c.*56T>A | 3'UTR (SNP) | VAF 37/77 reads (48%) | called by muse, mutect2, varscan2
- TRIM4 | c.*25T>G | 3'UTR (SNP) | VAF 93/282 reads (33%) | called by muse, mutect2, varscan2
- TRIM9 | c.1604-4101C>T | Intron (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- U2AF1L4 | c.-31del | 5'UTR (DEL) | VAF 35/117 reads (30%) | catalogued as COSV53077235; called by mutect2, pindel, varscan2
- ZC3H15 | c.-67C>T | 5'UTR (SNP) | VAF 17/49 reads (35%) | catalogued as rs1049229248; called by muse, mutect2, varscan2
- ZFP91 | c.857+61G>C | Intron (SNP) | VAF 4/23 reads (17%) | catalogued as rs1290209406; called by muse, mutect2
- ZSWIM6 | c.*353del | 3'UTR (DEL) | VAF 18/98 reads (18%) | called by pindel, varscan2
